Surgical pathology report (de-identified scan), TCGA case TCGA-22-5489, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5489-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED]

DIAGNOSIS:

Lung, left upper lobe, excision: Invasive grade 4 (of 4) squamous cell carcinoma forming a 2.7 x 2 x 1.8 cm mass located 0.7 cm from the bronchial margin. The surgical margins are negative. Multiple (3) intrapulmonary peribronchial lymph are negative for tumor.

Lung, superior segment left lower lobe, No. 1 excision: Microscopic squamous cell carcinoma in-situ forming a 0.2 cm lesion in diameter. The surgical margins are negative for tumor. [REDACTED]

Lung, superior segment left lower lobe, No. 2 excision: Negative for malignancy. Benign lung parenchyma.

Lymph nodes, superior and inferior mediastinal, aortic, and N1, excision: Multiple superior mediastinal (1 right upper paratracheal, 3 left lower paratracheal, 3 right lower paratracheal), aortic (2 aorto-pulmonary), inferior mediastinal (7 subcarinal, 3 inferior pulmonary ligament), and N1 (2 interlobar) lymph nodes are negative for tumor. Tissue submitted as right lower paratracheal lymph nodes shows necrotizing granulomas within the lymph nodes.

ADDENDUM:

The visceral pleural is not involved by neoplasm.
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file d5c5babd-af71-45ad-a335-76b117c023a3 (TCGA-22-5489.C83CBD0B-F2E0-42DF-B68E-4CA20DFBCE00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).